Somatic mutation profile of tumor specimen TCGA-AB-2924-03A (aliquot TCGA-AB-2924-03A-01W-0745-08) from TCGA case TCGA-AB-2924, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myelomonocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.8 years (21,825 days).
Specimen TCGA-AB-2924-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d56dc78-e903-4f7d-8b02-c29cd047863d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2924-11A (Solid Tissue Normal), aliquot TCGA-AB-2924-11A-01W-0745-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d64caad7-69ab-42e9-a884-b74e2b67393a

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIO2 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 55/102 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70445863, COSV70446327; called by mutect2, varscan2
- OR6M1 | c.277G>T p.A93S | Missense Mutation (SNP) | VAF 24/592 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.17); catalogued as COSV100484132; called by muse, mutect2
- PHLPP1 | c.1738G>C p.G580R | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53034658; called by muse, varscan2
